Somatic mutation profile of tumor specimen 0DJ6KL from CCDI case PBBWNN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,367 days).
Specimen 0DJ6KL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97cfa3f5-b322-4410-9a3a-b44cb62f3629.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ6K3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/331bb4c3-b086-4d3a-a3cb-6fe0b99e2484

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 3, Silent 1, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMCX5 | c.275C>A p.T92N | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV55765817; called by muse, mutect2
- ERC2 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 635/1184 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.515); catalogued as rs373270503; called by muse, mutect2, varscan2
- KALRN | c.3210del p.R1071Gfs*31 | Frame Shift Del (DEL) | VAF 92/300 reads (31%) | catalogued as COSV99561725, COSV99564534; called by mutect2, varscan2
- LCP1 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 169/542 reads (31%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as rs368627380, COSV59941193; called by muse, mutect2, varscan2
- SERPINB3 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 363/813 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs140650845, COSV52194780; called by muse, mutect2, varscan2
- TMC3 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 341/723 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770347299, COSV100845911; called by muse, mutect2, varscan2
- UBTF | c.2078A>G p.E693G | Missense Mutation (SNP) | VAF 251/1145 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1472027385; called by muse, mutect2, varscan2
- ZBED8 | c.1253G>T p.R418L | Missense Mutation (SNP) | VAF 430/1034 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as rs1196101709, COSV101283451; called by muse, mutect2, varscan2
- BARHL1 | c.472dup p.E158Gfs*75 | Frame Shift Ins (INS) | VAF 55/177 reads (31%) | called by mutect2, varscan2
- CTDNEP1 | c.607A>T p.K203* | Nonsense Mutation (SNP) | VAF 398/430 reads (93%) | called by muse, mutect2, varscan2
- HCLS1 | c.1331G>A p.S444N | Missense Mutation (SNP) | VAF 99/334 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- KCNIP3 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 29/685 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.577); called by muse, mutect2
- OR5L2 | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 297/981 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PCSK2 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 40/994 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2
- RBM27 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 385/893 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XIRP1 | c.351C>A p.P117= | Silent (SNP) | VAF 207/532 reads (39%) | called by muse, mutect2, varscan2
- ATF7IP | c.-8+19522T>A | Intron (SNP) | VAF 233/751 reads (31%) | called by muse, mutect2, varscan2
- BRCA1 | c.5074+85G>C | Intron (SNP) | VAF 13/338 reads (4%) | called by muse, mutect2
- H2AZ1 | c.4-20C>T | Intron (SNP) | VAF 210/360 reads (58%) | called by muse, mutect2, varscan2
